Somatic mutation profile of tumor specimen TCGA-27-2528-01A (aliquot TCGA-27-2528-01A-01D-1494-08) from TCGA case TCGA-27-2528, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.6 years (22,867 days).
Specimen TCGA-27-2528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b42152f-053d-4dae-a61d-715628d40a33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2528-10A (Blood Derived Normal), aliquot TCGA-27-2528-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f118894-652d-4ba4-b109-60e741dffc8b

The open-access MAF lists 55 somatic variants for this specimen: 46 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, Intron 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 138/433 reads (32%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58644502; called by muse, mutect2, varscan2
- ALPK2 | c.6219T>G p.S2073R | Missense Mutation (SNP) | VAF 102/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64493891; called by muse, mutect2, varscan2
- ANP32D | c.336A>C p.L112F | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV56980583; called by muse, mutect2, varscan2
- ATM | c.3279_3282del p.N1094Dfs*14 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | catalogued as rs879254281; called by pindel, varscan2
- BMP3 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51082815, COSV51086901; called by muse, mutect2, varscan2
- C3 | c.4325A>C p.N1442T | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV55574750; called by muse, mutect2, varscan2
- C7orf26 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV60106652; called by muse, mutect2
- CACNA1B | c.5531A>G p.H1844R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs759587821, COSV53130894; called by muse, mutect2, varscan2
- CELA3B | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs887057466, COSV61403460; called by muse, mutect2, varscan2
- CFAP47 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as rs1340321021, COSV52881153; called by muse, mutect2, varscan2
- CHID1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs373864240; called by muse, mutect2, varscan2
- CUL1 | c.1428C>G p.H476Q | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57389487; called by muse, mutect2, varscan2
- DNAH11 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs749125298, COSV60960806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs1021579404, COSV50015383; called by muse, mutect2, varscan2
- EFNB3 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs908477925, COSV56833660; called by muse, mutect2, varscan2
- EFS | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53732774; called by muse, mutect2, varscan2
- ENG | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61227743; called by muse, mutect2, varscan2
- FBXL5 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV58011925; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 37/92 reads (40%) | catalogued as rs752538869; called by mutect2, varscan2
- GABRA1 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV50107615; called by muse, mutect2, varscan2
- JMJD1C | c.5718A>T p.Q1906H | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59516032; called by muse, mutect2, varscan2
- KIF1A | c.5053C>T p.R1685W (on ENST00000320389 / NM_001379639.1; = p.R1677W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765668490, COSV57492343; ClinVar: uncertain significance; called by muse, mutect2
- LILRA2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs372106807; called by muse, mutect2, varscan2
- NDST4 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV52123520; called by muse, mutect2, varscan2
- NR4A1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770620910, COSV54483390; called by muse, mutect2, varscan2
- OR5W2 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60616573; called by muse, mutect2, varscan2
- PDCD11 | c.5402A>G p.Y1801C | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs377470805; called by muse, mutect2, varscan2
- PTPRO | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); catalogued as rs755573133, COSV55512745; called by muse, mutect2, varscan2
- RARS1 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV51564122; called by muse, mutect2
- RBMY1E | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV62777119; called by muse, mutect2, varscan2
- SLC35D3 | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV100090792, COSV59377894; called by muse, mutect2, varscan2
- SLC4A5 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.232); catalogued as rs1553453865, COSV61028856; called by muse, mutect2, varscan2
- SP110 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144163010; called by muse, mutect2, varscan2
- SPAM1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1287492496, COSV56144734; called by muse, mutect2, varscan2
- SPTA1 | c.4264G>A p.D1422N | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV63754809; called by muse, mutect2, varscan2
- SYNE1 | c.4724T>A p.L1575H (on ENST00000367255 / NM_182961.4; = p.L1582H on NM_033071.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55008406; called by muse, mutect2, varscan2
- UGGT1 | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs755677543, COSV52137090; called by muse, mutect2, varscan2
- ULK2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1409308441, COSV64446364; called by muse, mutect2, varscan2
- UNC45B | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs529858933, COSV52093267, COSV52101965; called by muse, mutect2, varscan2
- ZNF683 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as rs374469495, COSV62874659; called by muse, mutect2, varscan2
- CNTN2 | c.1399_1400del p.V467Nfs*16 | Frame Shift Del (DEL) | VAF 25/188 reads (13%) | called by mutect2, pindel, varscan2
- H2BC6 | c.186_188dup p.I62dup | In Frame Ins (INS) | VAF 90/308 reads (29%) | called by mutect2, pindel, varscan2
- PCDHGA7 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RAI14 | c.517del p.D173Ifs*32 | Frame Shift Del (DEL) | VAF 167/565 reads (30%) | called by mutect2, pindel, varscan2
- ZBED4 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.2520T>C p.F840= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV58839260; called by muse, mutect2, varscan2
- CPPED1 | c.639C>T p.I213= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as rs762127968, COSV55498497; called by muse, mutect2, varscan2
- FOXM1 | c.876C>T p.H292= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs373291558; called by muse, mutect2, varscan2
- NTSR1 | c.813C>T p.A271= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs377415240; called by muse, mutect2, varscan2
- PCDHB5 | c.1896C>T p.R632= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV50654939; called by muse, mutect2, varscan2
- UGT3A2 | c.1458C>T p.L486= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs762343800, COSV56928972; called by muse, mutect2, varscan2
- WDR48 | c.1332T>G p.S444= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV56532534; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33843C>T | Intron (SNP) | VAF 60/185 reads (32%) | catalogued as rs1396156223, COSV100280969; called by muse, mutect2, varscan2
- DCAF6 | c.1379-15334C>T | Intron (SNP) | VAF 19/69 reads (28%) | catalogued as rs371524406; called by muse, mutect2, varscan2
